Somatic mutation profile of tumor specimen TCGA-BQ-5884-01A (aliquot TCGA-BQ-5884-01A-11D-1589-08) from TCGA case TCGA-BQ-5884, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 59.5 years (21,730 days).
Specimen TCGA-BQ-5884-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 862235c4-17c9-4dfd-9a3c-e2f37576fda4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5884-11A (Solid Tissue Normal), aliquot TCGA-BQ-5884-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd576467-9e42-4a8a-9af9-a3ee029e693e

The open-access MAF lists 43 somatic variants for this specimen: 35 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 7, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1, Intron 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC2 | c.2221-1G>A p.X741_splice | Splice Site (SNP) | VAF 25/54 reads (46%) | catalogued as rs45517218, CS078610, COSV54761663, COSV99052715; ClinVar: pathogenic; called by muse, mutect2
- AKAP17A | c.917A>T p.Q306L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV58310369; called by muse, mutect2, varscan2
- ARHGAP26 | c.804G>C p.M268I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.186); catalogued as COSV50831290; called by muse, mutect2, varscan2
- ATG10 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.516); catalogued as COSV56426988; called by muse, mutect2, varscan2
- CPNE4 | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.134); catalogued as COSV70195191; called by muse, mutect2, varscan2
- CUBN | c.10557A>T p.R3519S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64717813; called by muse, mutect2
- DOCK2 | c.4184G>C p.G1395A | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV56959984, COSV56962922; called by muse, mutect2, varscan2
- ECPAS | c.1718T>C p.M573T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52199317; called by muse, mutect2, varscan2
- EEF1A1 | c.130A>G p.K44E | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.105); catalogued as COSV58549875; called by muse, mutect2
- EPC1 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.105); catalogued as COSV53926450, COSV99036450; called by muse, mutect2, varscan2
- F12 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.08); catalogued as rs1337905865, COSV53691644; called by muse, mutect2, varscan2
- FREM2 | c.4072A>G p.T1358A | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs778361178, COSV54840533; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1289C>G p.P430R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54563223; called by muse, mutect2, varscan2
- IRS1 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59337161; called by muse, mutect2, varscan2
- KIAA1109 | c.4447G>C p.E1483Q | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.214); catalogued as COSV52676896; called by muse, mutect2, varscan2
- METTL14 | c.1264T>A p.S422T | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.027); catalogued as COSV66310709; called by muse, mutect2, varscan2
- SIPA1L2 | c.293T>G p.L98R | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.143); catalogued as COSV53391963; called by muse, mutect2, varscan2
- SLC26A5 | c.1632T>G p.I544M | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.643); catalogued as COSV59702526; called by muse, mutect2, varscan2
- SLC7A13 | c.1333A>T p.R445* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV52534971; called by muse, mutect2, varscan2
- SOS1 | c.255G>A p.W85* | Nonsense Mutation (SNP) | VAF 29/101 reads (29%) | catalogued as COSV67675689; called by muse, mutect2, varscan2
- SRRM1 | c.818A>T p.K273M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as COSV60477976; called by muse, mutect2, varscan2
- STAT2 | c.1440G>A p.Q480= | Splice Region (SNP) | VAF 38/147 reads (26%) | catalogued as COSV58475931, COSV58477354; called by muse, mutect2, varscan2
- TIFA | c.323A>C p.K108T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64631857; called by muse, mutect2, varscan2
- TPT1 | c.343A>T p.M115L | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV58538860; called by muse, mutect2, varscan2
- UBE3C | c.2822A>G p.Q941R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.475); catalogued as rs1470742434, COSV61953717; called by muse, mutect2, varscan2
- ZBTB9 | c.164A>G p.Q55R | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67702157; called by muse, mutect2, varscan2
- ZC3H12C | c.2473T>A p.C825S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.777); catalogued as COSV53709376; called by muse, mutect2
- ZHX2 | c.2186A>C p.Q729P | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV58713847; called by muse, mutect2, varscan2
- ZNF292 | c.1318T>C p.W440R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60540640; called by muse, mutect2, varscan2
- ZNF33B | c.1861A>C p.K621Q | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV63942313, COSV63942676; called by muse, mutect2, varscan2
- ZNF532 | c.2111C>T p.T704I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs778677872, COSV100267378, COSV60173606; called by muse, mutect2, varscan2
- DENR | c.552+1del | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- IFIT5 | c.1431_1434dup p.R479Afs*45 | Frame Shift Ins (INS) | VAF 12/102 reads (12%) | called by mutect2, pindel, varscan2
- LRP2 | c.10193_10195del p.H3398del | In Frame Del (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- ZNF318 | c.448del p.I150Sfs*37 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- ANKIB1 | c.1992T>C p.Y664= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV56062608; called by muse, mutect2, varscan2
- MLNR | c.1113C>G p.L371= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV54532488, COSV54532976; called by muse, mutect2, varscan2
- PEF1 | c.279A>G p.P93= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV65483814; called by muse, mutect2, varscan2
- SLC38A10 | c.2400G>A p.Q800= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs755968510, COSV55846180; called by muse, mutect2, varscan2
- SLC39A5 | c.975C>G p.L325= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV99907583; called by muse, mutect2, varscan2
- TANC1 | c.4398C>A p.P1466= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as COSV55089384, COSV55098019; called by muse, mutect2, varscan2
- ZFP64 | c.846G>A p.S282= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV53800180, COSV99402870; called by muse, mutect2, varscan2
- EIF4G2 | c.1413+134dup | Intron (INS) | VAF 25/110 reads (23%) | called by mutect2, pindel, varscan2
